Somatic mutation profile of tumor specimen C3N-00383-04 (aliquot CPT0022830006) from CPTAC case C3N-00383, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.9 years (22,259 days).
Specimen C3N-00383-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 381cf566-1b4a-4f08-b13d-06078f7584b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00383-71 (Blood Derived Normal), aliquot CPT0020790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faf1bb5f-bda6-49ef-bd7a-ebe9ed80619c

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 2, RNA 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/326 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 34/147 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 38/191 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 88/442 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519724, COSV64288957, COSV64298985; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADGRG5 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs1248363404, COSV61082821; called by muse, mutect2, varscan2
- ATP1B4 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs777736864; called by muse, varscan2
- B3GALT1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422932467; called by muse, mutect2, varscan2
- BCOR | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs527732438, COSV60707971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.6541G>A p.A2181T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs766245468; called by muse, mutect2, varscan2
- CCS | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747428310, COSV59578241; called by muse, mutect2, varscan2
- CDC14C | c.1066G>A p.D356N (on ENST00000428251; = p.D249N on NM_152627.3) | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs747792639; called by muse, mutect2, varscan2
- DNAH10 | c.12202G>A p.E4068K (on ENST00000409039; = p.E4007K on NM_207437.3) | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV68990475; called by muse, mutect2, varscan2
- F13A1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs367679357, CM103181, COSV99344253; called by muse, mutect2, varscan2
- F5 | c.6304C>A p.R2102S | Missense Mutation (SNP) | VAF 93/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM030037, COSV63121893; called by muse, mutect2, varscan2
- FAM171B | c.2327G>C p.G776A | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs778464081; called by muse, mutect2, varscan2
- FBXL18 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs753018895; called by muse, mutect2, varscan2
- FZD10 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57473200; called by muse, mutect2, varscan2
- GPR176 | c.1215A>G p.I405M | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs868268156; called by muse, mutect2, varscan2
- LHCGR | c.470A>C p.D157A | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184908225; called by muse, mutect2, varscan2
- MAP3K7 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs751058214, COSV65226275; called by muse, mutect2, varscan2
- MAST4 | c.4490C>T p.P1497L (on ENST00000403625 / NM_001164664.2; = p.P1308L on NM_015183.3) | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.807); catalogued as COSV55140290; called by muse, mutect2, varscan2
- MCOLN1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs142665651; called by muse, mutect2, varscan2
- NHS | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196968, COSV66277330; called by muse, mutect2, varscan2
- PLEKHA2 | c.1183T>C p.S395P | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs1310205514; called by muse, mutect2, varscan2
- RGS11 | c.793G>A p.V265M (on ENST00000397770 / NM_183337.3; = p.V244M on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs766417162; called by muse, mutect2, varscan2
- SOX11 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58987239; called by muse, mutect2, varscan2
- TMEM183A | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as COSV100923812, COSV65888032; called by muse, mutect2, varscan2
- WDR11 | c.3365A>G p.N1122S | Missense Mutation (SNP) | VAF 118/522 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs1440785992, COSV99676343; called by muse, mutect2, varscan2
- ZDBF2 | c.5024G>A p.R1675Q | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs749703720, COSV65624340; called by muse, mutect2, varscan2
- ALDH3B1 | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL11B | c.1757C>T p.A586V (on ENST00000357195 / NM_001282237.2; = p.A515V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/435 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD3 | c.3236T>G p.V1079G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FHAD1 | c.4006G>T p.E1336* | Nonsense Mutation (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- GFRA4 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- HSPBAP1 | c.776T>G p.V259G | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- L1CAM | c.2589G>T p.K863N | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PBXIP1 | c.1891C>A p.Q631K | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIK3CG | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 58/246 reads (24%) | called by muse, varscan2
- PPP1R32 | c.737C>G p.T246S | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMC3 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM50 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CCDC157 | c.1173G>A p.A391= | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as rs1015366870; called by muse, mutect2, varscan2
- DNAJC13 | c.1614C>T p.A538= | Silent (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- EEF1A1 | c.501T>C p.Y167= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs777425489; called by muse, mutect2, varscan2
- FKBP1C | c.84C>T p.T28= | Silent (SNP) | VAF 82/348 reads (24%) | catalogued as rs561159358; called by muse, mutect2, varscan2
- H3-2 | c.75G>A p.A25= | Silent (SNP) | VAF 48/273 reads (18%) | catalogued as rs1394740728; called by muse, mutect2, varscan2
- LAG3 | c.1351C>T p.L451= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as rs1565482779; called by muse, mutect2, varscan2
- LAMA2 | c.1440T>C p.D480= | Silent (SNP) | VAF 105/480 reads (22%) | called by muse, mutect2, varscan2
- MAD2L1BP | c.135T>C p.A45= | Silent (SNP) | VAF 75/403 reads (19%) | called by muse, mutect2, varscan2
- MYO10 | c.627T>C p.N209= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs375432258; called by muse, mutect2, varscan2
- PLEKHN1 | c.1062C>T p.Y354= (on ENST00000379409; = p.Y302= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs771647949; called by muse, mutect2, varscan2
- PTPN21 | c.2289C>T p.H763= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100161763; called by muse, mutect2, varscan2
- SAMD3 | c.667C>A p.R223= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- SPIRE2 | c.1233G>A p.A411= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs774234787, COSV65556008; called by muse, mutect2, varscan2
- TMPRSS7 | c.111G>A p.P37= | Silent (SNP) | VAF 86/417 reads (21%) | catalogued as rs540320405, COSV69981987; called by muse, mutect2, varscan2
- WDR81 | c.2652C>A p.I884= | Silent (SNP) | VAF 74/318 reads (23%) | called by muse, mutect2, varscan2
- ZNF345 | c.747G>A p.Q249= | Silent (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- ZYG11A | c.1096A>C p.R366= | Silent (SNP) | VAF 40/252 reads (16%) | called by muse, mutect2, varscan2
- FMO6P | n.1829G>T | RNA (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- KNCN | c.*164C>T | 3'UTR (SNP) | VAF 42/202 reads (21%) | catalogued as rs755547562; called by muse, varscan2
- SNORD116-7 | n.27dup | RNA (INS) | VAF 60/316 reads (19%) | called by mutect2, pindel, varscan2
- TMEM44 | c.924+312G>A | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs752689275; called by muse, mutect2, varscan2
